TCGA case TCGA-FU-A40J — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Cervix uteri; Tissue source site: International Genomics Consortium. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/63dcfa32-c69e-45ad-bea3-ae672acb11c6

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 38 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, endocervical type: ICD-O-3 morphology code: 8384/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 38.8 years (14,182 days); Year of diagnosis: 2012; Method of diagnosis: Biopsy; AJCC pathologic T: T2a1; AJCC pathologic N: N1; AJCC pathologic M: MX; FIGO stage: Stage IIIB; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 4; Lymph nodes tested: 28; Lymphatic invasion present: Yes.
   Pathology details: Lymph node involved site: Pelvis, NOS.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 89 days; Days to treatment end: 196 days; Treatment dose: 4,500 cGy; Treatment outcome: Complete Response; Number of fractions: 25; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: 104 days; Days to treatment end: 306 days; Treatment outcome: Complete Response.

Follow-up (4 entries)
- Day 10 (preoperative): Days to imaging: 10 days; Imaging type: MRI; Imaging result: Negative; Imaging findings: Parametrium Involvement.
- Day 10 (preoperative): Days to imaging: 10 days; Imaging type: MRI; Imaging result: Negative; Imaging findings: Extra-Pelvic Metastatic Disease.
- Days to follow up: 41 days; Disease response: Tumor Free.
- Days to follow up: 426 days (1.2 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Hysterectomy type: Radical Hysterectomy.
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal; Pregnant at diagnosis: No.
- Timepoint category: Initial Diagnosis; Weight: 78 kg; Height: 160 cm; BMI: 30.5.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 3; Pregnancy outcome: Live Birth.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FU-A40J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 170 mg.
  Slide TCGA-FU-A40J-01A-01-TSA: Section location: Top; Percent tumor cells: 99; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 0; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-FU-A40J-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-FU-A40J-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Tumor status: Tumor free; Live birth pregnancy count: 3; Total pregnancy count: 3; Tobacco smoking history indicator: 1; Submitted tumor site: Cervical; Histologic diagnosis: Endocervical Type of Adenocarcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Lymph nodes examined: Yes; Lymphovascular invasion: Present; Corpus involvement: Absent; New tumor event diagnosis indicator: No.
- Lymph node location positive pathology names: Pos lymph node location: Pelvic (external iliac, internal iliac, obturator).
- Diagnostic mri result outcomes: Lymph nodes supraclavicular: Extra-Pelvic Metastatic Disease Absent; Lymph nodes supraclavicular: Parametrium Absent.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form, Treatment, Radiation therapy info: Radiation treatment reason not completed other: pt only received external beam tx - she moved during tx & brachytherapy was not scheduled due to travel constraints; Radiation therapy xrt type: External beam radiation.
- Follow-up form, Treatment, Concurrent prescription treatment info, Concurrent prescription treatment 2: Chemo concurrent type other: Taxol.
- Drug treatment 2: Pharmaceutical therapy drug name: Taxol.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 426 days; disease-specific survival: no event (censored), 426 days; disease-free interval: no event (censored), 426 days; progression-free interval: no event (censored), 426 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-FU-A40J-01A-11D-A242-01): tumor purity 0.65, ploidy 3.36, whole-genome doublings 1.
